Somatic mutation profile of tumor specimen TCGA-UZ-A9PS-01A (aliquot TCGA-UZ-A9PS-01A-11D-A42J-10) from TCGA case TCGA-UZ-A9PS, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II.
Specimen TCGA-UZ-A9PS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4485206d-6be7-4d34-831a-1a03dd17eef9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UZ-A9PS-10A (Blood Derived Normal), aliquot TCGA-UZ-A9PS-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a6f6736-ccec-4ad6-b809-81afd215d021

The open-access MAF lists 159 somatic variants for this specimen: 121 protein-altering or splice-affecting, 36 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 36, Frame Shift Del 16, Frame Shift Ins 6, Nonsense Mutation 4, In Frame Del 2, Splice Region 1, Intron 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.1461A>C p.K487N | Missense Mutation (SNP) | VAF 78/242 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99284471; called by muse, mutect2, varscan2
- AC104452.1 | c.988C>G p.P330A | Missense Mutation (SNP) | VAF 94/160 reads (59%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV99864336; called by muse, mutect2, varscan2
- ACAP2 | c.2294C>A p.P765Q | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100461278; called by muse, mutect2, varscan2
- ACE | c.3607C>G p.P1203A | Missense Mutation (SNP) | VAF 82/146 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99326202; called by muse, varscan2
- ADGRF3 | c.950A>T p.Q317L (on ENST00000311519 / NM_001145168.1; = p.Q118L on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100274678; called by muse, mutect2, varscan2
- AGGF1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 332/840 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0.029); catalogued as COSV100461370; called by muse, varscan2
- APC | c.6348T>G p.H2116Q | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.737); catalogued as rs1346330298, COSV99964485; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF28 | c.4275G>T p.Q1425H | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV99707965; called by muse, varscan2
- ATP5MC2 | c.415T>C p.F139L | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV100100901; called by muse, mutect2, varscan2
- BIRC3 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99679624; called by muse, mutect2, varscan2
- BRD1 | c.2187C>G p.C729W | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as COSV99349097; called by muse, mutect2, varscan2
- C1orf127 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as COSV100983381; called by muse, mutect2, varscan2
- CABLES1 | c.1283T>C p.L428P (on ENST00000256925 / NM_001100619.2; = p.L163P on NM_138375.2) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as COSV99908163; called by muse, mutect2, varscan2
- CACNA1E | c.6260A>C p.K2087T (on ENST00000367573 / NM_001205293.3; = p.K2044T on NM_000721.4) | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV100701185; called by muse, mutect2, varscan2
- CDH10 | c.545del p.V182Afs*44 | Frame Shift Del (DEL) | VAF 24/49 reads (49%) | catalogued as COSV100052183; called by mutect2, pindel, varscan2
- CERKL | c.247A>T p.K83* | Nonsense Mutation (SNP) | VAF 46/103 reads (45%) | catalogued as COSV100182935; called by muse, mutect2, varscan2
- CNTN1 | c.2059C>G p.L687V | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100750801; called by muse, mutect2, varscan2
- CUX1 | c.4073A>T p.Q1358L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.775); catalogued as COSV99470110; called by muse, mutect2, varscan2
- DPP6 | c.2458C>A p.P820T (on ENST00000377770 / NM_001364500.2; = p.P758T on NM_001936.5) | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs186233086, COSV100122515; called by muse, mutect2, varscan2
- EDNRB | c.1336A>C p.N446H (on ENST00000377211 / NM_001201397.1; = p.N356H on NM_000115.5) | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV100526099; called by muse, mutect2, varscan2
- FAAP20 | c.425C>A p.A142E | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV101051920; called by muse, mutect2, varscan2
- FAM217A | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV99212672; called by muse, mutect2, varscan2
- FOCAD | c.314T>G p.I105S | Missense Mutation (SNP) | VAF 174/421 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV100619915; called by muse, mutect2, varscan2
- FRAS1 | c.980G>T p.R327L | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV53654426, COSV99347273; called by muse, mutect2, varscan2
- GATAD1 | c.662T>A p.F221Y | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV55320390, COSV99843616; called by muse, mutect2, varscan2
- GLTP | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs1403190625, COSV100570223; called by muse, mutect2, varscan2
- GNAI2 | c.799C>A p.L267I | Missense Mutation (SNP) | VAF 73/100 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV99806746; called by muse, mutect2, varscan2
- GTF2H4 | c.341T>A p.F114Y | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as COSV52560119, COSV99461353; called by muse, mutect2, varscan2
- GZMK | c.379A>G p.K127E | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99140824; called by muse, mutect2, varscan2
- HNF1A | c.1273A>C p.T425P | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99981895; called by muse, mutect2, varscan2
- JAM3 | c.509A>C p.H170P | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.566); catalogued as COSV100137724; called by muse, mutect2, varscan2
- KIAA1109 | c.3749A>T p.K1250M | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); catalogued as COSV99145412; called by muse, mutect2, varscan2
- KIDINS220 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.075); catalogued as rs201363981; called by muse, mutect2, varscan2
- LRMDA | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1251866078, COSV100994288; called by muse, mutect2, varscan2
- LRRC66 | c.2054A>T p.E685V | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV100602777; called by muse, mutect2, varscan2
- MAST4 | c.3438T>A p.S1146R (on ENST00000403625 / NM_001164664.2; = p.S957R on NM_015183.3) | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as COSV99842452; called by muse, mutect2, varscan2
- MDP1 | c.454C>G p.Q152E | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99164576, COSV99164584; called by muse, mutect2, varscan2
- MED9 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV99245698; called by muse, mutect2
- MOB1B | c.452T>C p.I151T | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100511396; called by muse, mutect2, varscan2
- MORC3 | c.1262A>C p.K421T | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV101247704; called by muse, mutect2, varscan2
- MUC16 | c.32581T>G p.S10861A | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs554642180, COSV67467415; called by muse, mutect2, varscan2
- MYPN | c.1330T>A p.L444M | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); catalogued as COSV100589428, COSV100590707; called by muse, mutect2, varscan2
- NINL | c.1876A>C p.K626Q | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99624357; called by muse, mutect2, varscan2
- NRIP1 | c.3033T>A p.S1011R | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100012078; called by muse, mutect2, varscan2
- NRIP1 | c.3032G>T p.S1011I | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV100012080; called by muse, mutect2, varscan2
- NUP133 | c.1921T>A p.C641S | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV99772440; called by muse, mutect2, varscan2
- OBSCN | c.16900G>A p.A5634T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV99471075; called by muse, varscan2
- PAAF1 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100142278; called by muse, mutect2, varscan2
- PBLD | c.601A>T p.K201* | Nonsense Mutation (SNP) | VAF 49/144 reads (34%) | catalogued as COSV99515974; called by muse, mutect2, varscan2
- PCARE | c.247T>G p.S83A | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV100527220; called by muse, mutect2, varscan2
- PCBP1 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 54/114 reads (47%) | catalogued as COSV100340018, COSV57849597; called by muse, mutect2, varscan2
- PGAM5 | c.305T>A p.L102H | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100452911; called by muse, mutect2, varscan2
- PGM3 | c.22A>T p.K8* | Nonsense Mutation (SNP) | VAF 40/89 reads (45%) | catalogued as COSV99392130; called by muse, mutect2, varscan2
- PHYHD1 | c.176A>G p.E59G | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.664); catalogued as COSV100454900; called by muse, mutect2, varscan2
- PIK3AP1 | c.1804A>G p.T602A | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV100225396; called by muse, mutect2, varscan2
- PKHD1L1 | c.7063A>C p.N2355H | Missense Mutation (SNP) | VAF 79/246 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV101005112; called by muse, mutect2, varscan2
- PLEKHA4 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.72); catalogued as rs201822487, COSV99611944; called by muse, mutect2, varscan2
- POLG | c.3274-1G>C p.X1092_splice | Splice Site (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99174445; called by muse, mutect2, varscan2
- PRDM2 | c.1489A>G p.N497D | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99340560; called by muse, mutect2
- PSMD9 | c.490T>A p.S164T | Missense Mutation (SNP) | VAF 83/138 reads (60%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.724); catalogued as COSV99945514; called by muse, mutect2, varscan2
- RANBP3 | c.1244C>T p.S415L (on ENST00000340578 / NM_007322.3; = p.S410L on NM_003624.3) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV99222111; called by muse, mutect2, varscan2
- RGMA | c.332G>C p.S111T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV100223990; called by muse, mutect2, varscan2
- RILPL1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61552934; called by muse, mutect2, varscan2
- RIMBP2 | c.1966C>A p.L656M | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99898009; called by muse, mutect2
- RPRD2 | c.181C>A p.H61N | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.537); catalogued as COSV100954679; called by muse, mutect2, varscan2
- SCAF8 | c.2836A>G p.I946V | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.155); catalogued as COSV100913844; called by muse, mutect2, varscan2
- SELENON | c.1597A>T p.T533S | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV100823426; called by muse, mutect2, varscan2
- SEMA3E | c.1499G>T p.R500L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100316908, COSV57078209; called by muse, varscan2
- SESTD1 | c.965A>C p.Q322P | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV100090110; called by muse, mutect2, varscan2
- SLC3A2 | c.365dup p.Q123Afs*38 | Frame Shift Ins (INS) | VAF 40/126 reads (32%) | catalogued as rs778450636; called by mutect2, pindel, varscan2
- SLCO2B1 | c.2084T>C p.L695S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.034); catalogued as COSV99214149; called by muse, mutect2, varscan2
- SMCHD1 | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV55269538; called by muse, mutect2
- SPDEF | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.272); catalogued as rs766462365, COSV100927718; called by muse, mutect2, varscan2
- SPNS3 | c.255G>C p.L85F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100336811; called by muse, mutect2, varscan2
- SZT2 | c.7380A>T p.K2460N (on ENST00000634258 / NM_001365999.1; = p.K2403N on NM_015284.4) | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100986835; called by muse, mutect2, varscan2
- TBC1D22A | c.1394G>C p.R465T | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV100452511; called by muse, mutect2, varscan2
- TBK1 | c.471T>G p.D157E | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100537958; called by muse, mutect2, varscan2
- TBRG4 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.291); catalogued as COSV99345218; called by muse, mutect2, varscan2
- TDRD1 | c.1256A>T p.E419V | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99313846; called by muse, mutect2, varscan2
- TENT4A | c.898C>A p.L300M | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100048513; called by muse, mutect2, varscan2
- TET1 | c.6334T>G p.L2112V | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as COSV101017470; called by muse, mutect2, varscan2
- TM9SF2 | c.261del p.E88Kfs*52 | Frame Shift Del (DEL) | VAF 12/114 reads (11%) | catalogued as COSV64507014; called by mutect2, pindel, varscan2
- TMX2 | c.878A>G p.K293R | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs753219904, COSV99559608; called by muse, varscan2
- TP53BP1 | c.4061C>G p.S1354C | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV99779584; called by muse, mutect2, varscan2
- TRIP12 | c.5679T>C p.S1893= | Splice Region (SNP) | VAF 33/81 reads (41%) | catalogued as rs1195547009, COSV99389048; called by muse, mutect2, varscan2
- TTC39B | c.523A>G p.I175V | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as COSV99893857; called by muse, mutect2, varscan2
- TTR | c.406T>G p.Y136D | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52701473, COSV99379423; called by muse, mutect2, varscan2
- UPF1 | c.546G>T p.E182D | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99438630; called by muse, mutect2, varscan2
- UPF2 | c.2453A>T p.N818I | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV100706849; called by muse, mutect2
- UPF2 | c.2451G>T p.W817C | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs367800253, COSV100706850; called by muse, mutect2
- USH2A | c.12155T>G p.I4052S | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100227825; called by muse, mutect2, varscan2
- USP48 | c.1935T>A p.N645K | Missense Mutation (SNP) | VAF 192/486 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV100379354; called by muse, mutect2, varscan2
- USP53 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 124/319 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs775463286, COSV99917450; called by muse, mutect2, varscan2
- VPS13D | c.4294T>C p.Y1432H | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs753470639, COSV99165326; called by muse, mutect2, varscan2
- ZNF490 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100267115; called by muse, mutect2
- ZNF529 | c.808A>T p.T270S | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as COSV100485047; called by muse, mutect2, varscan2
- ZNF585B | c.559A>C p.K187Q | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.237); catalogued as COSV100459248; called by muse, mutect2, varscan2
- ZSCAN2 | c.1727A>G p.H576R | Missense Mutation (SNP) | VAF 84/161 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100306770; called by muse, mutect2, varscan2
- A4GALT | c.815_823del p.A272_R274del | In Frame Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- AGPAT2 | c.709del p.T237Lfs*16 | Frame Shift Del (DEL) | VAF 29/96 reads (30%) | called by mutect2, pindel, varscan2
- ANK2 | c.9882del p.N3294Kfs*13 | Frame Shift Del (DEL) | VAF 47/114 reads (41%) | called by mutect2, pindel, varscan2
- C1orf127 | c.1395del p.P467Qfs*21 | Frame Shift Del (DEL) | VAF 21/65 reads (32%) | called by mutect2, pindel, varscan2
- COL6A2 | c.2140_2150del p.L714Efs*24 | Frame Shift Del (DEL) | VAF 63/169 reads (37%) | called by mutect2, pindel*, varscan2*
- EPHA4 | c.1514del p.P505Lfs*57 | Frame Shift Del (DEL) | VAF 39/104 reads (38%) | called by mutect2, pindel, varscan2
- ERCC6 | c.2945dup p.L982Ffs*4 | Frame Shift Ins (INS) | VAF 31/76 reads (41%) | called by mutect2, pindel, varscan2
- F9 | c.891_918del p.I297Mfs*20 | Frame Shift Del (DEL) | VAF 71/219 reads (32%) | called by mutect2, pindel, varscan2
- FBXO38 | c.1989del p.L665Sfs*21 | Frame Shift Del (DEL) | VAF 111/273 reads (41%) | called by mutect2, pindel, varscan2
- GOLGA6A | c.856_857del p.P286Ifs*17 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | called by pindel, varscan2*
- GPR179 | c.6643A>T p.M2215L (on ENST00000621958; = p.M2214L on NM_001004334.4) | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHM | c.1411T>G p.F471V | Missense Mutation (SNP) | VAF 86/201 reads (43%) | SIFT deleterious (0.04); called by muse, mutect2, varscan2
- IMMP1L | c.461del p.L154Yfs*20 | Frame Shift Del (DEL) | VAF 129/407 reads (32%) | called by mutect2, pindel, varscan2
- KMT2C | c.8105_8106del p.K2702Rfs*3 | Frame Shift Del (DEL) | VAF 31/89 reads (35%) | called by mutect2, pindel, varscan2
- MAPRE1 | c.27_32del p.V10_T11del | In Frame Del (DEL) | VAF 46/83 reads (55%) | called by mutect2, pindel, varscan2
- NDST4 | c.2545dup p.L849Pfs*? | Frame Shift Ins (INS) | VAF 26/57 reads (46%) | called by mutect2, pindel, varscan2
- NPM1 | c.161dup p.D55Gfs*2 | Frame Shift Ins (INS) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- PRKCA | c.941del p.G314Afs*21 | Frame Shift Del (DEL) | VAF 59/222 reads (27%) | called by mutect2, pindel, varscan2
- R3HDM1 | c.990del p.F330Lfs*23 | Frame Shift Del (DEL) | VAF 49/143 reads (34%) | called by mutect2, pindel, varscan2
- SLC32A1 | c.765dup p.F256Lfs*3 | Frame Shift Ins (INS) | VAF 27/74 reads (36%) | called by mutect2, pindel, varscan2
- TUBB4B | c.365dup p.E123Gfs*3 | Frame Shift Ins (INS) | VAF 16/61 reads (26%) | called by mutect2, pindel, varscan2
- USP4 | c.2856del p.F952Lfs*76 | Frame Shift Del (DEL) | VAF 57/119 reads (48%) | called by mutect2, pindel, varscan2
- ZSWIM2 | c.474del p.K158Nfs*17 | Frame Shift Del (DEL) | VAF 25/57 reads (44%) | called by mutect2, pindel, varscan2
- ADGRF1 | c.2547G>T p.L849= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV99346869; called by muse, mutect2, varscan2
- AFF4 | c.3489T>A p.S1163= | Silent (SNP) | VAF 88/199 reads (44%) | catalogued as COSV99534472; called by muse, varscan2
- AP2A1 | c.1683C>T p.G561= | Silent (SNP) | VAF 18/142 reads (13%) | catalogued as rs775031716, COSV62818034; called by muse, mutect2, varscan2
- ATM | c.9015A>T p.V3005= | Silent (SNP) | VAF 47/66 reads (71%) | catalogued as COSV99586778; called by muse, mutect2, varscan2
- BRD2 | c.1680A>G p.A560= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as rs142074834; called by muse, mutect2, varscan2
- CALCA | c.90T>A p.S30= | Silent (SNP) | VAF 80/209 reads (38%) | catalogued as COSV100523866; called by muse, mutect2, varscan2
- CNTN6 | c.2412G>A p.L804= | Silent (SNP) | VAF 45/196 reads (23%) | catalogued as COSV100609797, COSV63173322; called by muse, mutect2, varscan2
- COL14A1 | c.201T>A p.T67= | Silent (SNP) | VAF 46/95 reads (48%) | catalogued as COSV99917608, COSV99921122; called by muse, mutect2, varscan2
- COQ6 | c.855T>C p.D285= | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as COSV99473684; called by muse, mutect2, varscan2
- CPSF7 | c.570T>C p.H190= (on ENST00000394888 / NM_001136040.4; = p.H233= on NM_024811.4) | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as rs774229020, COSV100466899; called by muse, mutect2, varscan2
- DOLK | c.1380C>A p.T460= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV100454901; called by muse, mutect2, varscan2
- DOT1L | c.1941A>T p.L647= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs758514909, COSV101288481; called by muse, mutect2, varscan2
- DUSP4 | c.636C>T p.A212= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV99529483; called by muse, mutect2, varscan2
- EDEM2 | c.273C>A p.V91= | Silent (SNP) | VAF 53/99 reads (54%) | catalogued as COSV100993608; called by muse, mutect2, varscan2
- H4C5 | c.60T>C p.R20= | Silent (SNP) | VAF 43/97 reads (44%) | catalogued as COSV100747844; called by muse, mutect2, varscan2
- HIPK2 | c.1629A>G p.S543= | Silent (SNP) | VAF 42/93 reads (45%) | catalogued as COSV100701926; called by muse, mutect2, varscan2
- KRT3 | c.651G>T p.R217= | Silent (SNP) | VAF 43/93 reads (46%) | catalogued as COSV58817062; called by muse, mutect2, varscan2
- KRTAP10-2 | c.678A>G p.R226= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV100551439; called by muse, mutect2, varscan2
- LPP | c.462T>G p.V154= | Silent (SNP) | VAF 102/193 reads (53%) | catalogued as COSV100446120; called by muse, mutect2, varscan2
- MAGI2 | c.1962A>T p.V654= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV100831987; called by muse, mutect2, varscan2
- MIDEAS | c.486T>A p.P162= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV99678505; called by muse, mutect2, varscan2
- MYO18A | c.1590G>A p.E530= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as COSV100571838; called by muse, mutect2, varscan2
- PKD1L2 | c.1857G>T p.L619= | Silent (SNP) | VAF 61/106 reads (58%) | catalogued as COSV100215976; called by muse, mutect2, varscan2
- PPP4R4 | c.1923T>C p.D641= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV100428175; called by muse, mutect2, varscan2
- PRKDC | c.10065G>A p.K3355= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as COSV100037975; called by muse, mutect2, varscan2
- SHROOM3 | c.5310G>T p.V1770= | Silent (SNP) | VAF 77/162 reads (48%) | catalogued as rs749739684, COSV99933314; called by muse, mutect2, varscan2
- STAB1 | c.4521C>T p.G1507= | Silent (SNP) | VAF 58/199 reads (29%) | catalogued as COSV100400984; called by muse, mutect2, varscan2
- TEX2 | c.2047C>A p.R683= | Silent (SNP) | VAF 112/174 reads (64%) | catalogued as COSV99366667, COSV99367608; called by muse, mutect2, varscan2
- THAP4 | c.1579A>C p.R527= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100398188; called by muse, mutect2, varscan2
- THAP4 | c.1578C>G p.A526= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV100398190; called by muse, mutect2, varscan2
- TOMM34 | c.471G>A p.R157= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as rs767367318, COSV100861863; called by muse, mutect2, varscan2
- TREH | c.582G>A p.K194= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV50622938, COSV99874092; called by muse, mutect2, varscan2
- TRIP12 | c.3147A>G p.T1049= | Silent (SNP) | VAF 44/93 reads (47%) | catalogued as COSV99389049; called by muse, mutect2, varscan2
- UTRN | c.279C>A p.V93= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV100839397, COSV100840707; called by muse, mutect2, varscan2
- ZFP37 | c.1449T>C p.H483= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV100953137; called by muse, mutect2, varscan2
- ZNF749 | c.876C>T p.L292= | Silent (SNP) | VAF 48/121 reads (40%) | catalogued as rs1271651491, COSV61946063; called by muse, mutect2, varscan2
- EIF4A2 | c.771+105A>G | Intron (SNP) | VAF 64/117 reads (55%) | catalogued as COSV99960927; called by muse, mutect2, varscan2
- SSX6P | n.276C>T | RNA (SNP) | VAF 103/252 reads (41%) | catalogued as rs1460177666; called by muse, mutect2, varscan2
